TARGET case TARGET-30-PAMXYK — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Kidney. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/ad38f368-eadf-57fb-86ec-585d20886bc1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.2 years (1,157 days); Year of diagnosis: 2004; Days to last follow up: 959 days (2.6 years); INSS stage: Stage 4.
